Somatic mutation profile of tumor specimen TCGA-DK-A2I1-01A (aliquot TCGA-DK-A2I1-01A-11D-A17V-08) from TCGA case TCGA-DK-A2I1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 73.2 years (26,726 days).
Specimen TCGA-DK-A2I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56691085-bba8-4bfd-bcde-b287d80e4f9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A2I1-10A (Blood Derived Normal), aliquot TCGA-DK-A2I1-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f767da5-0dd8-4072-82fc-7113fd92ff95

The open-access MAF lists 245 somatic variants for this specimen: 174 protein-altering or splice-affecting, 62 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 62, Nonsense Mutation 16, Intron 5, Splice Site 4, In Frame Ins 2, Frame Shift Ins 2, RNA 1, 3'UTR 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOT8 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323429867, COSV54170164; called by muse, mutect2, varscan2
- ADAM10 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53052465; called by muse, mutect2, varscan2
- ADAMTS16 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs774739746, COSV56991304, COSV99943233; called by muse, mutect2, varscan2
- ADCY1 | c.873C>G p.F291L | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV52036844; called by muse, mutect2, varscan2
- AGGF1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs751143437, COSV57229732; called by muse, mutect2, varscan2
- ANKRD6 | c.1808C>T p.A603V (on ENST00000339746 / NM_001242809.2; = p.A598V on NM_014942.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV60232889; called by mutect2, varscan2
- AQP7 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV53020499; called by muse, mutect2, varscan2
- ARF5 | c.331-1G>A p.X111_splice | Splice Site (SNP) | VAF 23/109 reads (21%) | catalogued as COSV50001335; called by mutect2, varscan2
- ARHGAP26 | c.1641C>G p.I547M | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.829); catalogued as COSV50832011, COSV50832662, COSV50836679; called by muse, mutect2, varscan2
- ATP6V1A | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 195/400 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56362990; called by muse, mutect2, varscan2
- BBOX1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54191828; called by muse, mutect2, varscan2
- BTF3L4 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV57629760; called by muse, mutect2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 28/79 reads (35%) | catalogued as rs372345940; called by mutect2, varscan2
- CACNB2 | c.791C>G p.P264R (on ENST00000324631 / NM_201596.3; = p.P209R on NM_000724.4) | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV56632153, COSV99993645; called by muse, mutect2, varscan2
- CACNG8 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.963); catalogued as rs750396252, COSV54415420, COSV99555140; called by muse, mutect2, varscan2
- CASP3 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV57725313; called by muse, mutect2, varscan2
- CCNF | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53540902; called by mutect2, varscan2
- CD226 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.187); catalogued as COSV54613507, COSV99711199; called by muse, mutect2, varscan2
- CD6 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs936172100, COSV57839952; called by muse, mutect2, varscan2
- CDAN1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs373881679; called by mutect2, varscan2
- CELSR2 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV54774368; called by mutect2, varscan2
- CFAP44 | c.1879C>G p.P627A | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV55612862; called by muse, varscan2
- CHD4 | c.4072G>C p.E1358Q (on ENST00000357008 / NM_001363606.2; = p.E1371Q on NM_001273.5) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58904142; called by muse, mutect2, varscan2
- CHD4 | c.3856G>C p.E1286Q (on ENST00000357008 / NM_001363606.2; = p.E1299Q on NM_001273.5) | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.382); catalogued as COSV58904155; called by muse, mutect2, varscan2
- COL14A1 | c.3442G>C p.D1148H | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52861802; called by muse, mutect2, varscan2
- COMP | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs312262899, CM990431, COSV55875289; called by muse, mutect2, varscan2
- CTNND2 | c.2439G>C p.K813N | Missense Mutation (SNP) | VAF 94/461 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58899373; called by mutect2, varscan2
- CYP3A7 | c.1122G>C p.E374D | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.44); catalogued as COSV60482048; called by muse, mutect2, varscan2
- DCLRE1C | c.682C>G p.H228D (on ENST00000378278 / NM_001350965.2; = p.H113D on NM_022487.4) | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM101619, COSV63184078; called by muse, mutect2, varscan2
- DDX60 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV67097448; called by muse, mutect2, varscan2
- DENND3 | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs754976184, COSV52802080; called by muse, varscan2
- DENND5B | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60904068; called by muse, mutect2, varscan2
- DGKH | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV54932061, COSV54934742; called by muse, mutect2, varscan2
- DNAH8 | c.4192G>C p.E1398Q | Missense Mutation (SNP) | VAF 114/148 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59457518; called by muse, mutect2, varscan2
- DSCAM | c.3556G>C p.E1186Q | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV68029567; called by muse, mutect2
- DTNA | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.24); catalogued as rs772037079, COSV52009590; called by muse, mutect2, varscan2
- DYNC2H1 | c.10766G>T p.W3589L | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV62097540; called by muse, mutect2, varscan2
- ELF4 | c.248-1G>C p.X83_splice | Splice Site (SNP) | VAF 56/234 reads (24%) | catalogued as COSV57453275; called by muse, mutect2, varscan2
- EPHA5 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.585); catalogued as COSV56652439, COSV99899377; called by muse, mutect2
- ERP44 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs140289515, COSV52432812; called by mutect2, varscan2
- EXOC1 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV62120798; called by mutect2, varscan2
- EXOC4 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as COSV54118103; called by muse, mutect2, varscan2
- FAM160B1 | c.688C>A p.H230N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as COSV65088570; called by muse, varscan2
- FBH1 | c.1849G>C p.E617Q (on ENST00000362091 / NM_178150.3; = p.E668Q on NM_032807.4) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV62983124, COSV62983378; called by muse, varscan2
- FBL | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371072739; called by muse, mutect2, varscan2
- FBXL13 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV57534677; called by muse, mutect2, varscan2
- FCGR3B | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376361357; called by muse, mutect2
- GART | c.2234A>G p.Q745R | Missense Mutation (SNP) | VAF 134/383 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV67818891; called by muse, mutect2, varscan2
- GCLC | c.1267G>C p.G423R (on ENST00000643939; = p.G421R on NM_001498.4) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57596151; called by muse, varscan2
- GGA2 | c.1004G>C p.R335T | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.4); catalogued as COSV59169027; called by muse, varscan2
- GPR156 | c.1439C>A p.S480Y | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs1393477240, COSV104410614, COSV59940708; called by mutect2, varscan2
- GRAP2 | c.75G>C p.L25F | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59995847; called by muse, mutect2, varscan2
- GTPBP2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV61076631; called by muse, mutect2, varscan2
- GZMA | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV57113630; called by muse, varscan2
- GZMM | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV52742449; called by muse, mutect2, varscan2
- HAS2 | c.1062G>A p.W354* | Nonsense Mutation (SNP) | VAF 28/151 reads (19%) | catalogued as COSV58262885; called by muse, mutect2, varscan2
- HDAC4 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759438761; called by mutect2, varscan2
- HELZ2 | c.3865G>C p.E1289Q (on ENST00000467148 / NM_001037335.2; = p.E720Q on NM_033405.3) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV71296211; called by muse, mutect2, varscan2
- HELZ2 | c.3373G>A p.E1125K (on ENST00000467148 / NM_001037335.2; = p.E556K on NM_033405.3) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV64409923; called by muse, varscan2
- HIPK3 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57563439; called by muse, mutect2, varscan2
- HNRNPA1 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV52937381, COSV52937625; called by muse, mutect2, varscan2
- IARS2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV56960862; called by muse, mutect2, varscan2
- IMPA1 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV56271931; called by muse, mutect2, varscan2
- INPP4A | c.2261C>G p.S754C (on ENST00000074304 / NM_001134224.1; = p.S715C on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); catalogued as COSV50789350, COSV50798924; called by muse, mutect2, varscan2
- ITGAL | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1428037729, COSV63322859; called by muse, mutect2, varscan2
- KCNIP4 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752727409, COSV54842738; called by mutect2, varscan2
- KMT2D | c.15689G>T p.C5230F | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56454639, COSV99040085; called by muse, mutect2, varscan2
- KRT71 | c.651G>C p.K217N | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57291335, COSV99922331; called by muse, mutect2, varscan2
- KRT75 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52873488; called by mutect2, varscan2
- KRTAP13-1 | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100819865, COSV62663087, COSV62663667; called by muse, mutect2
- LAMC3 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs377457257; called by muse, varscan2
- LCTL | c.998A>C p.K333T | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV57181115; called by muse, mutect2, varscan2
- LIG3 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.062); catalogued as rs748659769, COSV52008639; called by mutect2, varscan2
- LINGO1 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV62436912, COSV62437449; called by muse, mutect2, varscan2
- LTV1 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753858250, COSV62536558; called by muse, mutect2, varscan2
- LYST | c.6643G>A p.D2215N | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.069); catalogued as COSV67708692; called by muse, mutect2, varscan2
- MACF1 | c.3223G>A p.A1075T | Missense Mutation (SNP) | VAF 48/114 reads (42%) | catalogued as COSV58378914; called by muse, mutect2, varscan2
- MARF1 | c.1127G>C p.R376T | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV60025149; called by muse, mutect2, varscan2
- MCM3AP | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52441417; called by mutect2, varscan2
- MED13 | c.2188G>T p.D730Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV101180770, COSV67264518; called by mutect2, varscan2
- MKS1 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58304745; called by muse, varscan2
- MLST8 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV57029336; called by muse, mutect2, varscan2
- MUC16 | c.28241G>A p.R9414K | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.346); catalogued as COSV67475567; called by muse, mutect2, varscan2
- MUC17 | c.2639C>A p.S880Y | Missense Mutation (SNP) | VAF 188/565 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60292830; called by muse, varscan2
- NAB1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61608953; called by muse, mutect2, varscan2
- NKTR | c.1425G>C p.M475I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV51768971, COSV51773003; called by muse, mutect2, varscan2
- NOP2 | c.1109G>A p.G370E (on ENST00000322166 / NM_001258308.2; = p.G366E on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV59110178, COSV59111622; called by muse, mutect2, varscan2
- NR1H2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV53801181; called by muse, mutect2, varscan2
- NRG1 | c.80G>A p.G27D (on ENST00000523534; = p.G174D on NM_013962.2) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73061426; called by mutect2, varscan2
- NT5DC2 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV58738559, COSV58744029; called by muse, mutect2, varscan2
- OR2G2 | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV60740966; called by muse, varscan2
- OR2G2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60740985; called by muse, mutect2, varscan2
- OR2G2 | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.044); catalogued as COSV60740024, COSV60741005; called by muse, varscan2
- OR2G2 | c.919G>T p.V307F | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV60741013; called by muse, varscan2
- OSBPL5 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.359); catalogued as COSV55142797; called by muse, mutect2, varscan2
- P3H1 | c.466-1G>C p.X156_splice | Splice Site (SNP) | VAF 50/152 reads (33%) | catalogued as COSV52534751; called by muse, mutect2, varscan2
- PCDH9 | c.2857G>A p.D953N | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.88); catalogued as COSV60562080; called by muse, mutect2, varscan2
- PCLO | c.9697G>A p.E3233K | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1312568013, COSV61643926; called by muse, mutect2, varscan2
- PEX12 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV56778376; called by mutect2, varscan2
- PGLYRP2 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV52995129; called by muse, mutect2, varscan2
- PHF6 | c.790G>C p.D264H (on ENST00000332070 / NM_032458.3; = p.D265H on NM_032335.3) | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59703786; called by muse, mutect2, varscan2
- PHLDB2 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 146/469 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as rs1023762535, COSV67312767; called by muse, mutect2, varscan2
- PIF1 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs374923447; called by mutect2, varscan2
- PKDCC | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.661); catalogued as COSV54307336; called by muse, mutect2, varscan2
- PLEC | c.11299G>C p.E3767Q (on ENST00000322810 / NM_201380.4; = p.E3657Q on NM_000445.5) | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59652214; called by muse, mutect2, varscan2
- PLEKHA4 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV54361139; called by muse, mutect2, varscan2
- POSTN | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV101123471, COSV65713447; called by muse, mutect2, varscan2
- PRAMEF4 | c.555G>C p.K185N | Missense Mutation (SNP) | VAF 95/455 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as COSV99340150; called by muse, mutect2, varscan2
- PRDM10 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.165); catalogued as rs910497766, COSV58802263; called by muse, mutect2, varscan2
- PRKG1 | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV64834678; called by muse, varscan2
- PRMT9 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as COSV59360163; called by muse, mutect2, varscan2
- PRRG3 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs1019184963, COSV64851214; called by mutect2, varscan2
- PSMD1 | c.1414-1G>C p.X472_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV58080203; called by muse, mutect2, varscan2
- PTPRD | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.643); catalogued as COSV61957412; called by muse, mutect2, varscan2
- PUS7 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs776732227, COSV62675630; called by muse, mutect2, varscan2
- QSER1 | c.3886C>G p.L1296V (on ENST00000399302; = p.L1425V on NM_001076786.3) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV67901022; called by muse, mutect2, varscan2
- RALGAPA1 | c.3080C>G p.S1027C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV51887342; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1732C>G p.L578V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as COSV52788478, COSV99216529; called by muse, varscan2
- RASEF | c.353C>A p.S118* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV61550876; called by muse, mutect2, varscan2
- RHOA | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV69042869; called by muse, mutect2, varscan2
- RPAP3 | c.1727C>G p.S576C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV50042103; called by muse, mutect2, varscan2
- RPGRIP1 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as rs1345736757, COSV52851774; called by muse, mutect2, varscan2
- RTF1 | c.511T>A p.S171T | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV67478352; called by mutect2, varscan2
- RXFP3 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.356); catalogued as rs767134913, COSV57506435; called by mutect2, varscan2
- SCN3A | c.4428G>C p.K1476N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV51814208, COSV51815911; called by muse, mutect2, varscan2
- SCUBE1 | c.2396G>A p.G799D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62612224, COSV62613497; called by muse, varscan2
- SELENBP1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64373658; called by muse, varscan2
- SELENBP1 | c.220C>G p.H74D | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64373663; called by muse, varscan2
- SEMA3G | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV51596362; called by muse, varscan2
- SEPTIN11 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV53583033; called by muse, mutect2, varscan2
- SHISA5 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs1268825921, COSV56497806, COSV99604175; called by mutect2, varscan2
- SLC12A5 | c.1981G>A p.E661K (on ENST00000454036 / NM_001134771.2; = p.E638K on NM_020708.5) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV54795957; called by muse, varscan2
- SLC25A31 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55419834; called by muse, mutect2, varscan2
- SPI1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV57045424; called by muse, mutect2, varscan2
- SPRR1A | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs774846454, COSV61081288; called by muse, mutect2, varscan2
- SPTBN4 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV58952802; called by mutect2, varscan2
- SPTY2D1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.837); catalogued as COSV60474301; called by muse, mutect2, varscan2
- STAG3 | c.3239G>A p.G1080E | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV57931800; called by muse, mutect2, varscan2
- SZT2 | c.6182C>G p.S2061C (on ENST00000634258 / NM_001365999.1; = p.S2004C on NM_015284.4) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV65171053; called by muse, mutect2, varscan2
- TAMM41 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 38/98 reads (39%) | catalogued as rs769048276; called by mutect2, varscan2
- TBK1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748622208, CM152640, COSV59156377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TDGF1 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs767305917, COSV56126763, COSV99947579; called by muse, mutect2, varscan2
- THOC2 | c.3673G>A p.E1225K | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as COSV55548987; called by muse, mutect2, varscan2
- TMEM102 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV53440247; called by muse, mutect2, varscan2
- TMEM143 | c.231C>G p.F77L | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV53157210; called by muse, mutect2
- TMEM260 | c.1662C>G p.F554L | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV55100538; called by muse, mutect2, varscan2
- TMEM97 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as COSV56878917; called by muse, mutect2, varscan2
- TRERF1 | c.2534C>T p.S845F | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61673750; called by muse, varscan2
- TRERF1 | c.2488C>G p.L830V | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV61673771; called by muse, varscan2
- TRPC3 | c.1895C>A p.A632E (on ENST00000379645 / NM_001366479.2; = p.A559E on NM_003305.2) | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53377169; called by muse, mutect2, varscan2
- TRPM2 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55971688, COSV55979774; called by muse, mutect2, varscan2
- UBR1 | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51931889; called by muse, mutect2, varscan2
- UROS | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754180409, COSV64223698; called by muse, varscan2
- USP6 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV51485873; called by muse, mutect2, varscan2
- USPL1 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV55000537; called by muse, mutect2, varscan2
- VPS50 | c.2284C>T p.L762F | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59919730; called by muse, mutect2, varscan2
- WDR46 | c.1130C>G p.S377C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV65851796; called by muse, mutect2, varscan2
- ZNF623 | c.937C>G p.H313D | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71697238; called by muse, mutect2, varscan2
- AC002094.3 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- CENPE | c.3757G>T p.E1253* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | called by muse, mutect2, varscan2
- CNOT1 | c.5152C>T p.R1718* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | called by mutect2, varscan2
- CSRNP2 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 54/154 reads (35%) | called by muse, mutect2, varscan2
- DDX5 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | called by mutect2, varscan2
- EIF4ENIF1 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | called by muse, varscan2
- MRM1 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PIK3C2B | c.4185_4186insGTT p.N1395_T1396insV | In Frame Ins (INS) | VAF 46/207 reads (22%) | called by mutect2, pindel*, varscan2*
- PLEKHS1 | c.688G>T p.E230* (on ENST00000369310 / NM_182601.1; = p.E236* on NM_024889.5) | Nonsense Mutation (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.2512C>T p.Q838* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | called by mutect2, varscan2
- SCN4B | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- SLC25A30 | c.810_811insTTA p.L270dup | In Frame Ins (INS) | VAF 42/112 reads (38%) | called by mutect2, pindel, varscan2
- SRGAP2 | c.2135C>G p.S712* (on ENST00000624873 / NM_001170637.4; = p.S713* on NM_015326.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | called by muse, varscan2
- ZFP36L1 | c.419dup p.I141Hfs*40 | Frame Shift Ins (INS) | VAF 40/101 reads (40%) | called by mutect2, pindel, varscan2
- ZNF611 | c.1232C>G p.S411* | Nonsense Mutation (SNP) | VAF 50/134 reads (37%) | called by muse, mutect2, varscan2
- ACTL10 | c.243G>A p.K81= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs1218599185, COSV55776900; called by muse, mutect2, varscan2
- ADAM11 | c.738C>T p.I246= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV52344333; called by mutect2, varscan2
- APBA1 | c.2364C>T p.I788= | Silent (SNP) | VAF 56/62 reads (90%) | catalogued as COSV55230522; called by muse, mutect2, varscan2
- ARHGAP5 | c.2313G>A p.K771= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs1215131716, COSV61536935; called by muse, varscan2
- ARHGEF2 | c.1125C>T p.L375= (on ENST00000361247 / NM_001162383.2; = p.L347= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs756510235, COSV58112622; called by mutect2, varscan2
- CBLC | c.1176G>A p.E392= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV54322165, COSV54323541; called by muse, mutect2, varscan2
- CDK12 | c.1696C>T p.L566= | Silent (SNP) | VAF 78/367 reads (21%) | catalogued as COSV71001329, COSV99067787; called by muse, mutect2, varscan2
- COL5A1 | c.351C>T p.V117= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV65670692; called by muse, mutect2, varscan2
- CXCR1 | c.672C>T p.F224= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as rs199972612, COSV55282305; called by muse, mutect2, varscan2
- DBF4B | c.1770C>T p.L590= | Silent (SNP) | VAF 50/95 reads (53%) | catalogued as rs1243312463, COSV59261509; called by muse, mutect2, varscan2
- DDX4 | c.1593C>G p.L531= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV61755679, COSV61757319; called by muse, mutect2, varscan2
- DNAH5 | c.1458C>T p.I486= | Silent (SNP) | VAF 73/152 reads (48%) | catalogued as COSV54234252; called by muse, mutect2, varscan2
- DNAJC11 | c.1026G>A p.K342= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV53787902; called by muse, mutect2, varscan2
- EFTUD2 | c.1212G>A p.T404= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs200389815; ClinVar: likely benign; called by mutect2, varscan2
- FAM160B1 | c.726C>T p.L242= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV65088580; called by muse, varscan2
- FGF13 | c.159C>T p.H53= | Silent (SNP) | VAF 72/237 reads (30%) | catalogued as COSV65430077; called by muse, mutect2, varscan2
- GAK | c.3465G>A p.V1155= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV58506242; called by mutect2, varscan2
- HSD17B2 | c.900C>T p.I300= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs747758320, COSV52276782; called by muse, mutect2, varscan2
- IDH3B | c.1050G>A p.K350= | Silent (SNP) | VAF 76/510 reads (15%) | catalogued as COSV61390448; called by muse, mutect2, varscan2
- LXN | c.405C>T p.L135= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as COSV51833583, COSV51834209; called by muse, mutect2, varscan2
- MAP3K15 | c.549C>T p.F183= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV58832675; called by mutect2, varscan2
- MCHR1 | c.564C>T p.I188= | Silent (SNP) | VAF 48/101 reads (48%) | catalogued as COSV50760316; called by muse, mutect2, varscan2
- MEF2C | c.105G>A p.L35= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs560463589, COSV60933743; called by mutect2, varscan2
- MS4A3 | c.87G>C p.L29= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs1317840476, COSV53936712; called by muse, varscan2
- MTHFR | c.1224G>C p.L408= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as COSV57173070; called by muse, varscan2
- MTMR11 | c.609G>A p.E203= (on ENST00000439741 / NM_001145862.2; = p.E131= on NM_181873.3) | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs1553768446, COSV63806966; called by muse, mutect2, varscan2
- MYH10 | c.4350G>A p.Q1450= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52604122; called by muse, mutect2, varscan2
- MYH7 | c.5499C>T p.N1833= | Silent (SNP) | VAF 79/133 reads (59%) | catalogued as rs3729831; ClinVar: benign / likely benign / uncertain significance; called by mutect2, varscan2
- NCKAP5 | c.1338C>G p.L446= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV58452983; called by muse, mutect2, varscan2
- NDUFB4 | c.129G>A p.L43= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV51742487; called by muse, mutect2, varscan2
- NPTXR | c.1374C>T p.V458= | Silent (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- OR14K1 | c.414C>A p.L138= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV51721654, COSV99315423; called by mutect2, varscan2
- OSBPL10 | c.312C>T p.I104= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV67340784; called by muse, mutect2, varscan2
- PARP6 | c.1866G>A p.V622= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV53003791; called by muse, mutect2, varscan2
- PGLYRP2 | c.279G>C p.L93= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV52995152; called by muse, mutect2, varscan2
- PGLYRP2 | c.117G>A p.Q39= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV52995172; called by muse, varscan2
- PIH1D2 | c.315C>T p.V105= | Silent (SNP) | VAF 39/207 reads (19%) | catalogued as COSV54775778; called by muse, mutect2, varscan2
- PLAAT2 | c.405G>A p.T135= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs771244500, COSV55374673, COSV55375090; called by mutect2, varscan2
- PLCB3 | c.2958C>T p.V986= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV54189713; called by mutect2, varscan2
- PROKR2 | c.1101C>G p.L367= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV54087352; called by muse, mutect2, varscan2
- PSG2 | c.321G>A p.L107= | Silent (SNP) | VAF 74/612 reads (12%) | catalogued as COSV68884890; called by mutect2, varscan2
- PSMC2 | c.66C>T p.I22= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs755684671, COSV50791572; called by muse, mutect2, varscan2
- RABGEF1 | c.912C>T p.I304= (on ENST00000439720 / NM_001287061.2; = p.I291= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV53163061; called by mutect2, varscan2
- RABL2A | c.686G>A p.*229= | Silent (SNP) | VAF 11/54 reads (20%) | called by mutect2, varscan2
- RALGAPA1 | c.915C>T p.V305= | Silent (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- RELN | c.5541G>A p.R1847= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV59011672, COSV59041992; called by muse, mutect2, varscan2
- RENBP | c.879C>T p.S293= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as rs199613622, COSV64170104; called by muse, mutect2, varscan2
- RPL10L | c.519C>T p.F173= | Silent (SNP) | VAF 66/128 reads (52%) | catalogued as rs1304848419, COSV53560361; called by muse, mutect2, varscan2
- RRP1B | c.954C>T p.H318= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV61479405; called by muse, mutect2, varscan2
- SLC7A3 | c.438G>A p.K146= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV53227992; called by muse, varscan2
- SOCS6 | c.573G>A p.L191= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV67546639; called by mutect2, varscan2
- THUMPD3 | c.1170C>T p.I390= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV61506248; called by muse, mutect2, varscan2
- TICRR | c.5508G>C p.R1836= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV51542811; called by muse, mutect2, varscan2
- TMEM97 | c.57C>T p.L19= | Silent (SNP) | VAF 11/32 reads (34%) | called by mutect2, varscan2
- TTC37 | c.498C>T p.F166= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV62455373; called by muse, mutect2, varscan2
- TTLL3 | c.2613C>T p.P871= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV59614399; called by muse, varscan2
- USP35 | c.1515C>G p.L505= | Silent (SNP) | VAF 63/180 reads (35%) | catalogued as COSV71573054; called by muse, mutect2, varscan2
- VNN2 | c.861G>C p.V287= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV58473014; called by muse, mutect2
- XRN1 | c.1986G>A p.L662= | Silent (SNP) | VAF 25/217 reads (12%) | catalogued as COSV53813841; called by muse, mutect2, varscan2
- ZBTB39 | c.1194C>T p.F398= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV55629432; called by muse, mutect2, varscan2
- ZNF292 | c.6720C>T p.D2240= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV60541466; called by muse, mutect2, varscan2
- ZSWIM4 | c.915C>G p.L305= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV54323319; called by muse, varscan2
- AL136439.1 | chr13:27665692 G>A | 3'Flank (SNP) | VAF 16/60 reads (27%) | catalogued as COSV68799745; called by muse, mutect2, varscan2
- ANKRD13D | c.*560C>T | 3'UTR (SNP) | VAF 8/48 reads (17%) | catalogued as COSV57753123; called by mutect2, varscan2
- CTSA | c.-49G>C | 5'UTR (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99510109; called by muse, mutect2
- HIGD1A | c.-23+248G>C | Intron (SNP) | VAF 84/222 reads (38%) | catalogued as COSV58415113; called by muse, mutect2, varscan2
- IGKV1-13 | n.149G>A | RNA (SNP) | VAF 108/270 reads (40%) | catalogued as rs1385448423; called by muse, varscan2
- NFATC3 | c.3107-11933C>G | Intron (SNP) | VAF 45/99 reads (45%) | catalogued as COSV60475453; called by muse, mutect2, varscan2
- PRR22 | c.194-74C>G | Intron (SNP) | VAF 17/172 reads (10%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-1974A>G | Intron (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100389500, COSV57630612; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23400C>T | Intron (SNP) | VAF 19/74 reads (26%) | catalogued as COSV59381349; called by mutect2, varscan2
